Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A5SM, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A5SM-01A (Primary Tumor).

[page 1 of 2]
Note: If you do not see "END OF PRINTED REPORT" at the bottom of the report **YOU DO NOT HAVE THE ENTIRE REPORT**. Please try print

CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected

Time Reported

Order Number

Status

Final

Ordering Provider

Relevant
Information

Location

Copied To

Report Patient
Demographics
(for verification
purposes)

Name

Date of Birth:

Sex: M

ICD-O-3

Carcinoma, hepatocellular NOS

817013

Site: Liver, hepatic, C22.0

QD 4/2/13

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist

Specimen Description

- A. Gallbladder
- B. HCC tumor left lobe
- C. Deep margin
- D. Final margin liver lobe left

Clinical Information

Infectious patient: Yes - Hep +

Cirrhosis, hepatocellular carcinoma?

Diagnosis

A. Gallbladder, Cholecystectomy:

- Gallbladder with no pathologic abnormality.

B. Liver, (Left Lobe), Wedge Resection:

- Hepatocellular carcinoma, Grade III/IV
- The tumor measures 2.7 cm in maximal dimension
- Carcinoma is present at the cauterized/inked parenchymal margin in this specimen (see comment)
- Focal small vessel invasion is seen within the tumor itself
- No perineural invasion identified
- Cirrhosis of the surrounding liver parenchyma

[page 2 of 2]
- C. Liver, (Deep Margin), Excision:
- Negative for hepatocellular carcinoma.
- D. Liver, (Final Margin), Excision:
- Negative for hepatocellular carcinoma.

Gross Description

A. The specimen is designated "Gallbladder". The specimen is received fresh and is subsequently placed into formalin and consists of a gallbladder that measures 10.0 x 4.0 x 4.0 cm. Opening the gallbladder reveals approximately 10 ml of dark green bile. The serosa of the gallbladder appears unremarkable as does the mucosal surface. There are no stones present. A section of mucosa is submitted in cassette A1.

B. The specimen is designated "HCC tumor left lobe". The specimen is received fresh and is subsequently placed into formalin and consists of a piece of liver that weighs 43.8 g and measures 4.0 x 4.5 x 4.0 cm. There is a solitary firm, tan nodule present at the inked margin of the specimen and this nodule measures 2.7 x 2.7 x 2.5 cm. The surrounding liver parenchyma is cirrhotic. Random sections of the tumor are submitted in cassettes B1 to B5. B6 contains uninvolved cirrhotic liver parenchyma.

C. The specimen is designated "Deep margin". The specimen consists of a small fragment of firm brown tissue that measures 1.0 x 0.8 x 0.2 cm. It is submitted in toto in cassette C1.

D. The specimen is designated "Final margin liver lobe left". The specimen consists of a firm brown friable tissue that measures 1.1 x 1.0 x 0.2 cm. This is submitted in toto in cassette D1.

Pathologist Comment

Accession
Number
Encounter
Number
Patient Location

- END OF PRINTED REPORT -

Prognosis Discrepancy	☒	☒
Tumor Site User Spancy	☒	☒
Primary Site User Spancy	☒	☒
Primary Multiple History	☒	☒
Non-Response Primary Noted		
Overall Rating	BTR	17613

Source: NCI Genomic Data Commons file 9200dbea-f710-41bc-853b-d86403cc884a (TCGA-G3-A5SM.791E29AD-22A6-402E-978C-69407C6B748F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).